Somatic mutation profile of tumor specimen TARGET-10-PANWJS-09A (aliquot TARGET-10-PANWJS-09A-01D) from TARGET case TARGET-10-PANWJS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,021 days).
Specimen TARGET-10-PANWJS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a8aa949-5e1b-4ea1-8c59-56f5cfceb090.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWJS-10A (Blood Derived Normal), aliquot TARGET-10-PANWJS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3749632e-f4c4-47c7-99cc-e428a0bbed63

The open-access MAF lists 58 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, 3'UTR 2, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 23/102 reads (23%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CCDC170 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201381723, COSV53340772; called by muse, varscan2
- COL6A5 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.336); catalogued as COSV55195642; called by muse, mutect2, varscan2
- DGKK | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.761); catalogued as rs782276961, COSV101052826; called by muse, mutect2
- DGKK | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs782720256, COSV65707161, COSV65708645; called by muse, mutect2, varscan2
- DYRK1A | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs1470299902, COSV100118232, COSV58292124; called by muse, mutect2, varscan2
- GK2 | c.388del p.I130Ffs*23 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs771628988; called by mutect2, pindel, varscan2
- KATNIP | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs747200027, COSV55189452; called by mutect2, varscan2
- MARK4 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs763202566, COSV53465896; called by muse, mutect2, varscan2
- N4BP2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs780859612; called by muse, mutect2, varscan2
- NOP2 | c.316C>T p.R106C (on ENST00000322166 / NM_001258308.2; = p.R102C on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs762968722; called by muse, mutect2, varscan2
- PMS1 | c.997A>G p.M333V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1357259764; called by muse, mutect2, varscan2
- PWWP3B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV61798513; called by muse, mutect2, varscan2
- RAP1GAP | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99266222; called by muse, mutect2, varscan2
- SERPINA11 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV58242029, COSV58243030; called by muse, mutect2, varscan2
- TGFBR2 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV55448358, COSV55453645; called by muse, mutect2, varscan2
- TGFBR2 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746373651; called by muse, mutect2, varscan2
- TMPRSS9 | c.1415C>A p.A472D (on ENST00000648592; = p.A438D on NM_182973.2) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as COSV60229291; called by muse, mutect2
- ZNF462 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs777645034, COSV52934398; called by muse, mutect2, varscan2
- ACSM2B | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ARMCX5 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2
- BICRAL | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL6A5 | c.4454G>A p.G1485E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIP2B | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, varscan2
- ENAM | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- FAM210A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRS4 | c.2903T>A p.F968Y | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- JMJD1C | c.1660T>A p.L554M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- KIAA0100 | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRTAP10-9 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LAS1L | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC4C | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP7D2 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PANK1 | c.1270G>T p.V424L (on ENST00000307534 / NM_148977.2; = p.V199L on NM_138316.4) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PER1 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TTN | c.57932G>A p.S19311N (on ENST00000591111; = p.S11887N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | PolyPhen benign (0.098); called by muse, mutect2, varscan2
- UACA | c.2501G>T p.C834F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.115); called by muse, mutect2
- USP34 | c.4519G>C p.E1507Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF736 | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTN4 | c.1587C>T p.I529= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as rs753950086, COSV61868231; called by muse, mutect2
- FAM122B | c.651G>A p.P217= (on ENST00000370790 / NM_001166599.3; = p.P218= on NM_145284.5) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs1245364579; called by muse, mutect2, varscan2
- FAM184A | c.3420C>T p.F1140= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- FREM2 | c.6747T>C p.T2249= | Silent (SNP) | VAF 38/84 reads (45%) | called by muse, varscan2
- HMOX1 | c.837G>A p.A279= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as rs752370833; called by muse, mutect2, varscan2
- JMJD1C | c.1659C>T p.F553= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- KCNJ8 | c.858C>A p.A286= | Silent (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- MBTPS2 | c.1491C>T p.I497= | Silent (SNP) | VAF 17/285 reads (6%) | catalogued as COSV65269891; called by muse, mutect2
- OGG1 | c.42T>A p.R14= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- OR2G6 | c.453C>T p.S151= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs774470186, COSV100598332, COSV58573644; called by muse, mutect2, varscan2
- OR52I2 | c.988C>T p.L330= | Silent (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- OR56A4 | c.459C>T p.F153= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV58111450; called by muse, mutect2, varscan2
- PNPLA6 | c.2178C>A p.G726= (on ENST00000414982 / NM_001166111.2; = p.G678= on NM_006702.5) | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- PROKR1 | c.903C>T p.Y301= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs374654942; called by muse, mutect2, varscan2
- RAP1GAP | c.825G>A p.T275= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs140749955; called by muse, mutect2, varscan2
- UBR3 | c.3288T>A p.L1096= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- TIMP1 | c.453+59C>T | Intron (SNP) | VAF 18/121 reads (15%) | catalogued as rs1446472569, COSV99512129; called by muse, mutect2, varscan2
- TRPM8 | c.*7A>G | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- XIAP | c.*842C>T | 3'UTR (SNP) | VAF 18/62 reads (29%) | catalogued as rs1015138148; called by muse, mutect2, varscan2
